Somatic mutation profile of tumor specimen 0DB11G from CCDI case PBBKSP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.0 years (1,816 days).
Specimen 0DB11G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 871d928c-0efe-481e-a77e-cd61529f8ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB11Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78553ef2-021d-4523-a4f9-1e23feb4470c

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 342/706 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 21/632 reads (3%) | catalogued as COSV59989381; called by muse, mutect2
- ITGA5 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 94/182 reads (52%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.793); catalogued as rs377645220; called by muse, mutect2, varscan2
- MTMR11 | c.2119G>T p.D707Y | Missense Mutation (SNP) | VAF 266/614 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs373466760; called by mutect2, varscan2
- MUC4 | c.14692C>A p.Q4898K (on ENST00000463781 / NM_018406.7; = p.Q662K on NM_004532.6) | Missense Mutation (SNP) | VAF 52/879 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs754525521; called by muse, mutect2
- SCP2 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 68/1057 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746849767, COSV101026715; called by muse, mutect2
- KANK2 | c.153T>A p.D51E | Missense Mutation (SNP) | VAF 164/365 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- OBSL1 | c.4840G>A p.D1614N | Missense Mutation (SNP) | VAF 170/346 reads (49%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SLC45A4 | c.2161G>A p.E721K (on ENST00000517878 / NM_001286646.2; = p.E670K on NM_001080431.2) | Missense Mutation (SNP) | VAF 22/698 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.077); called by muse, mutect2
- AFF3 | c.1683C>T p.A561= | Silent (SNP) | VAF 156/300 reads (52%) | catalogued as COSV57852962; called by muse, mutect2, varscan2
- DROSHA | c.267G>A p.A89= | Silent (SNP) | VAF 133/371 reads (36%) | catalogued as rs375941240, COSV60778044; called by muse, mutect2, varscan2
- KRTAP10-4 | c.852C>T p.V284= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs368809950; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- INPP5E | c.-43G>T | 5'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PTBP1 | c.892+68C>T | Intron (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
